Gene-level copy-number profile of tumor specimen TCGA-EY-A1GS-01A from TCGA case TCGA-EY-A1GS, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 71.2 years (26,012 days).
Specimen TCGA-EY-A1GS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.0902cfd2-1f9f-4114-a4d0-6ed304cd569f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EY-A1GS-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/555210e1-ea1d-47cd-bcae-05c83b1a3fec

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 244; copy number 2: 15,766; copy number 3: 15,691; copy number 4: 12,448; copy number 5: 8,945; copy number 6: 5,198; copy number 7: 464; copy number 8: 217; copy number 9: 49; copy number 10: 18; copy number 11: 44; copy number 12: 19; copy number 15: 23; copy number 16: 282; copy number 18: 65; copy number 20: 11; copy number 21: 220; copy number 23: 92; copy number 27: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EY-A1GS-01A-11D-A13J-01): tumor purity 0.81, ploidy 3.61, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:48,389,567–48,444,704, 2 genes: LPAR6, Metazoa_SRP.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,487 genes in 33 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:234,356,704–234,736,720, 20 genes, copy number 11: AL355472.1, AL355472.2, AL355472.3, COA6-AS1, COA6, TARBP1, LINC01354, AL161640.2, AL161640.3, AL161640.1, U8, IRF2BP2, AL160408.2, LINC00184, AL160408.5, AL160408.1, AL160408.4, AL160408.3, AL160408.6, LINC01132.
- chr2:9,103,440–9,146,106, 4 genes, copy number 9: AC093904.2, AC093904.4, AC093904.3, AC093904.1.
- chr2:12,702,764–13,007,029, 5 genes, copy number 8: AC009486.2, AC009486.1, TRIB2, MIR3125, AC064875.1.
- chr2:173,880,850–174,043,880, 5 genes, copy number 7: SP3, AC016737.1, AC016737.2, LINC01960, RPSAP24.
- chr2:186,486,253–186,509,361, 2 genes, copy number 11: ZC3H15, DPRXP1.
- chr3:155,742,142–156,817,062, 24 genes, copy number 8: AC104472.1, AC104472.2, C3orf33, AC104472.3, SLC33A1, AC104472.4, GMPS, AC104472.5, SETP14, VN2R1P, KCNAB1, ALG1L15P, MRE11P1, AC091607.2, AC091607.1, KCNAB1-AS2, KCNAB1-AS1, AC084036.1, SSR3, TIPARP-AS1, TIPARP, METTL15P1, LINC00886, PA2G4P4.
- chr3:169,083,499–169,939,175, 20 genes, copy number 8–12 (within-gene range 5–12): MECOM, MECOM-AS1, RPL22P1, AC007849.1, SDHDP3, RNU6-637P, TERC, Telomerase-vert, ACTRT3, AC078802.1, MYNN, AC078795.1, LRRC34, AC078795.3, AC078795.2, LRRIQ4, LRRC31, KRT18P43, SAMD7, AC008040.2.
- chr5:58,198–43,886,628, 694 genes, copy number 7–23 (broad region; genes not listed).
- chr6:43,844,878–44,830,188, 27 genes, copy number 7 (within-gene range 3–7): LINC02537, AL157371.1, AL109615.3, C6orf223, AL109615.2, AL109615.1, AL109615.4, MRPL14, TMEM63B, CAPN11, RN7SL811P, MYMX, SLC29A1, HSP90AB1, SLC35B2, MIR4647, NFKBIE, TMEM151B, AL353588.1, TCTE1, AARS2, SPATS1, CDC5L, MIR4642, AL136140.1, AL136140.2, AL133334.1.
- chr6:132,271,982–132,519,295, 4 genes, copy number 12: EEF1A1P36, MOXD1, STX7, RPL21P66.
- chr6:138,161,939–138,422,197, 6 genes, copy number 11 (within-gene range 5–11): ARFGEF3, PBOV1, SMIM28, AL031003.1, MARCKSL1P2, HEBP2.
- chr6:138,435,213–138,464,383, 2 genes, copy number 11: MIR3145, AL391669.1.
- chr7:63,768,257–67,362,950, 157 genes, copy number 8–21 (broad region; genes not listed).
- chr7:71,307,672–71,307,770, 2 genes, copy number 7: MIR3914-1, MIR3914-2.
- chr7:86,876,906–87,220,587, 7 genes, copy number 8 (within-gene range 3–8): ELAPOR2, AC004023.1, AC005076.1, DMTF1, AC005076.2, TMEM243, Y_RNA.
- chr7:88,420,167–101,629,296, 318 genes, copy number 16–27 (within-gene range 3–27) (broad region; genes not listed).
- chr7:102,973,522–103,514,007, 18 genes, copy number 7 (within-gene range 3–7): NFE4, AC073127.1, ARMC10, CRYZP1, NAPEPLD, AC007683.1, RPL23AP95, AC007683.3, DPY19L2P2, S100A11P1, PMPCB, DNAJC2, PSMC2, RPS29P16, SLC26A5, Y_RNA, Y_RNA, AC005064.1.
- chr9:102,995,311–103,065,598, 2 genes, copy number 7: CYLC2, AL589823.1.
- chr10:33,578,931–35,647,826, 34 genes, copy number 15–20: LINC02628, AL450313.1, LINC00838, RPL23P11, LINC02629, PARD3, Y_RNA, ELOBP4, RPL37P18, RPS12P16, PARD3-AS1, SS18L2P1, RNU6-847P, RNU6-193P, PRDX2P2, LINC02635, CUL2, MIR3611, AL392046.1, CREM, RNU7-77P, ATP6V1G1P4, AL117336.1, LINC02634, RNU6-794P, CCNY, RNU6-1167P, AL117336.2, AL603824.1, AL121749.1, GJD4, FZD8, AL121749.2, MIR4683.
- chr10:86,052,448–87,357,882, 38 genes, copy number 7 (within-gene range 2–7): RNA5SP322, MIR346, AL844892.2, AL844892.1, WAPL, RNU6-780P, AL731569.1, RPL7AP8, OPN4, LDB3, AC067750.1, BMPR1A, RPAP2P1, RNU1-19P, MMRN2, AC025268.1, SNCG, ADIRF-AS1, ADIRF, AL136982.7, AGAP11, BMS1P3, AL136982.1, AL136982.6, AL136982.4, AL136982.2, FAM25A, AL136982.5, RNU6-529P, GLUD1, SHLD2, AL136982.3, RN7SL733P, NUTM2A-AS1, AL157893.2, AL157893.1, NUTM2A, LINC00863.
- chr10:110,642,678–111,013,666, 14 genes, copy number 11 (within-gene range 6–11): Y_RNA, RBM20, RN7SKP288, RNA5SP327, AL136368.1, PDCD4-AS1, PDCD4, MIR4680, BBIP1, AL158163.2, AL158163.1, SHOC2, RPL13AP6, MIR548E.
- chr10:126,393,489–127,452,517, 9 genes, copy number 9 (within-gene range 6–9): AL589787.2, LINC00601, C10orf90, AL589787.1, AL512272.1, DOCK1, AL359094.1, AL359094.2, INSYN2A.
- chr12:51,238,724–51,392,867, 5 genes, copy number 7 (within-gene range 3–7): DAZAP2, SMAGP, BIN2, CELA1, GALNT6.
- chr13:61,409,685–61,427,946, 3 genes, copy number 10: PCDH20, AL592490.1, LINC02339.
- chr13:73,036,401–73,227,260, 6 genes, copy number 8: PSMD10P3, KLF5, FABP5P1, RNU6-66P, RNU4-10P, RNY1P8.
- chr13:90,060,247–90,231,682, 5 genes, copy number 10: LINC00559, RNA5SP34, FAR1P1, KRT18P27, MIR622.
- chr17:32,258,615–32,491,253, 18 genes, copy number 9: AC026620.2, RHBDL3, AC026620.1, AC005899.4, C17orf75, AC005899.3, OOSP1P2, MIR632, ZNF207, AC005899.6, AC005899.7, AC005899.5, AC005899.8, AC005899.1, AC005899.2, PSMD11, Y_RNA, CDK5R1.
- chr17:32,495,536–32,531,492, 7 genes, copy number 9: AC079336.5, AC079336.7, AC079336.2, AC079336.1, AC079336.6, AC079336.4, AC079336.3.
- chr17:74,609,885–74,747,335, 4 genes, copy number 8 (within-gene range 5–8): CD300E, AC064805.2, RAB37, CD300LF.
- chr20:17,956,979–18,059,188, 1 gene, copy number 7 (within-gene range 4–7): OVOL2.
- chr20:17,969,018–18,467,281, 20 genes, copy number 7–9 (within-gene range 4–9): MGME1, PTMAP3, AL160411.1, RPL15P1, RNU7-137P, Y_RNA, KAT14, PET117, GGCTP2, RN7SL14P, RNU2-56P, AL049646.2, ZNF133, AL049646.1, RN7SKP74, ZNF133-AS1, LINC00851, DZANK1, GCNT1P1, RNA5SP476.
- chr22:39,743,044–39,893,864, 1 gene, copy number 8 (within-gene range 5–8): ENTHD1.
- chr22:39,874,255–40,043,534, 5 genes, copy number 8 (within-gene range 5–8): RN7SKP210, UQCRFS1P1, GRAP2, Z82206.1, FAM83F.

Autosomal genes at a single copy (total copy number 1): 244. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
